Somatic mutation profile of tumor specimen TCGA-BR-A4PD-01A (aliquot TCGA-BR-A4PD-01A-11D-A25D-08) from TCGA case TCGA-BR-A4PD, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Fundus of stomach; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 72.1 years (26,334 days).
Specimen TCGA-BR-A4PD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 50b9990a-3778-4e44-ad71-abea8467f0e5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-A4PD-10A (Blood Derived Normal), aliquot TCGA-BR-A4PD-10A-01D-A25E-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2b12f3f7-f3e2-4d43-9645-997cbbea9c30

The open-access MAF lists 166 somatic variants for this specimen: 124 protein-altering or splice-affecting, 39 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 113, Silent 39, Nonsense Mutation 5, Frame Shift Del 3, RNA 2, In Frame Del 1, Frame Shift Ins 1, 3'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LCE1A | c.83A>G p.K28R | Missense Mutation (SNP) | VAF 21/175 reads (12%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV58726434, COSV58726966, COSV58727394; called by muse, mutect2, varscan2
- TP53 | c.273G>A p.W91* | Nonsense Mutation (SNP) | VAF 89/147 reads (61%) | hotspot (GDC flag); catalogued as rs876660548, CM065495, COSV52673580; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAM12 | c.719G>A p.R240Q | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs927992573, COSV64106760, COSV64109341; called by muse, mutect2, varscan2
- ADAMTS12 | c.1723A>G p.K575E | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.14); catalogued as COSV61263073; called by muse, mutect2, varscan2
- ADRA2A | c.1091C>T p.P364L | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.3); PolyPhen benign (0.052); catalogued as rs1283596786, COSV54527879, COSV54530600; called by mutect2, varscan2
- AGFG1 | c.1535A>C p.N512T | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.265); catalogued as COSV59512005; called by muse, mutect2, varscan2
- AL592490.1 | c.1750T>G p.L584V | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.063); catalogued as COSV69426264; called by muse, mutect2, varscan2
- AMY2A | c.196A>G p.I66V | Missense Mutation (SNP) | VAF 86/134 reads (64%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs749935390, COSV70214501; called by muse, mutect2, varscan2
- ARHGAP12 | c.299T>C p.L100P | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.248); catalogued as COSV60963303; called by muse, mutect2, varscan2
- ASTE1 | c.303G>T p.Q101H | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.942); catalogued as COSV53908691; called by muse, mutect2, varscan2
- ATG7 | c.262T>G p.Y88D | Missense Mutation (SNP) | VAF 65/160 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.136); catalogued as COSV61612461; called by muse, mutect2, varscan2
- ATP10D | c.3199G>T p.A1067S | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV56707413; called by muse, mutect2, varscan2
- BPIFB6 | c.560A>C p.K187T | Missense Mutation (SNP) | VAF 33/257 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV62755204; called by muse, mutect2, varscan2
- CACNA1E | c.991T>G p.F331V | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV62394720; called by muse, mutect2, varscan2
- CASS4 | c.1099G>A p.E367K | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as COSV64386472, COSV64387410; called by muse, mutect2, varscan2
- CD1E | c.253T>G p.F85V | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as COSV100937010, COSV63770217; called by muse, mutect2, varscan2
- CELSR1 | c.7089G>A p.R2363= | Splice Region (SNP) | VAF 14/45 reads (31%) | catalogued as COSV53090160; called by muse, mutect2, varscan2
- CES1 | c.124G>A p.G42R | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1304520987, COSV62088307; called by muse, mutect2
- CLEC4D | c.388T>G p.F130V | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.664); catalogued as COSV55228354, COSV55228413, COSV55229108; called by muse, mutect2, varscan2
- CLSTN2 | c.1891A>T p.I631F | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.067); catalogued as COSV71720876; called by muse, mutect2, varscan2
- CNTNAP2 | c.2834T>G p.V945G | Missense Mutation (SNP) | VAF 46/79 reads (58%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.646); catalogued as COSV62181555; called by muse, mutect2, varscan2
- COL4A1 | c.3115T>G p.L1039V | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.661); catalogued as COSV65425668; called by muse, mutect2, varscan2
- CRACR2A | c.736A>G p.S246G | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as COSV52912844; called by muse, mutect2, varscan2
- CSK | c.718A>G p.M240V | Missense Mutation (SNP) | VAF 43/75 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); catalogued as COSV54973833; called by muse, mutect2, varscan2
- CSMD1 | c.9361A>C p.S3121R (on ENST00000520002; = p.S3120R on NM_033225.6) | Missense Mutation (SNP) | VAF 60/193 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV59278385, COSV59291937; called by muse, mutect2, varscan2
- CTAG2 | c.263T>A p.L88H | Missense Mutation (SNP) | VAF 5/89 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.937); catalogued as COSV55994928; called by muse, mutect2
- CUL1 | c.37A>C p.K13Q | Missense Mutation (SNP) | VAF 131/203 reads (65%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.717); catalogued as COSV57388654; called by muse, mutect2, varscan2
- CYLC1 | c.1205A>C p.K402T | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.324); catalogued as COSV61412148; called by muse, mutect2, varscan2
- DDX21 | c.1558T>G p.S520A | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.326); catalogued as COSV62555732; called by muse, mutect2, varscan2
- DENND5B | c.2874G>T p.W958C | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60902569; called by muse, mutect2, varscan2
- DLGAP1 | c.1426G>A p.V476M | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT tolerated (0.82); PolyPhen benign (0.158); catalogued as rs748701251, COSV59787361, COSV59822489; called by muse, mutect2, varscan2
- DNAH3 | c.4367C>A p.S1456Y | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54521592; called by muse, mutect2, varscan2
- DNAH9 | c.7918T>G p.F2640V | Missense Mutation (SNP) | VAF 58/209 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.344); catalogued as COSV52349655; called by muse, mutect2, varscan2
- EIF2AK3 | c.1290A>C p.K430N | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.722); catalogued as COSV57547625; called by muse, mutect2, varscan2
- ELAPOR2 | c.2220A>C p.K740N (on ENST00000450689 / NM_001142749.3; = p.K573N on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/181 reads (13%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.738); catalogued as COSV51886865; called by muse, mutect2, varscan2
- ERBB4 | c.3820A>T p.I1274F | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.543); catalogued as COSV61487525; called by muse, mutect2, varscan2
- ETNPPL | c.1226T>G p.L409R | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV56595774; called by muse, mutect2, varscan2
- FAM111A | c.385C>T p.R129C | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs202134817; called by muse, mutect2, varscan2
- FAM135B | c.1933A>C p.S645R | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.235); catalogued as rs756192058, COSV52714592; called by muse, mutect2, varscan2
- FLG | c.7534A>C p.S2512R | Missense Mutation (SNP) | VAF 101/653 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.088); catalogued as rs773788883, COSV64241812, COSV64245918; called by muse, mutect2, varscan2
- FOLH1 | c.530T>G p.V177G | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57049127; called by muse, mutect2, varscan2
- GABRA4 | c.1105A>G p.R369G | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV51927622; called by muse, mutect2, varscan2
- GPM6B | c.176T>C p.L59P | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57422470; called by muse, mutect2, varscan2
- GRM3 | c.1075T>C p.F359L | Missense Mutation (SNP) | VAF 25/254 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV64471672; called by muse, mutect2, varscan2
- GSDMC | c.1168T>A p.F390I | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.64); PolyPhen benign (0.011); catalogued as COSV52695449; called by muse, mutect2
- GTF3C1 | c.5975G>T p.G1992V | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62241262; called by muse, mutect2, varscan2
- HRNR | c.2804A>G p.K935R | Missense Mutation (SNP) | VAF 89/515 reads (17%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs1460816225, COSV64257958; called by muse, mutect2, varscan2
- HUWE1 | c.3235G>T p.V1079F | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as COSV53345500; called by muse, mutect2
- IGHG1 | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 24/186 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as rs1408409840; called by muse, mutect2, varscan2
- IRAG1 | c.515A>G p.E172G | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV70210901; called by muse, mutect2, varscan2
- IVL | c.986A>G p.Q329R | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.813); catalogued as COSV64216226; called by muse, mutect2
- KLHL4 | c.1223T>G p.L408R | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100908996; called by mutect2, varscan2
- LTBP1 | c.2956A>G p.S986G (on ENST00000404816 / NM_206943.4; = p.S660G on NM_000627.4) | Missense Mutation (SNP) | VAF 19/148 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.438); catalogued as rs762768648, COSV63186976; called by muse, mutect2, varscan2
- MAGEA12 | c.715T>A p.F239I | Missense Mutation (SNP) | VAF 75/241 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.237); catalogued as COSV63294807; called by muse, mutect2, varscan2
- MID1IP1 | c.272A>G p.Y91C | Missense Mutation (SNP) | VAF 81/131 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61230647; called by muse, mutect2, varscan2
- MMP17 | c.502A>G p.S168G | Missense Mutation (SNP) | VAF 20/243 reads (8%) | SIFT tolerated (0.42); PolyPhen benign (0.159); catalogued as COSV62179351; called by muse, mutect2
- MYH13 | c.4324G>A p.A1442T | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0.04); PolyPhen benign (0.04); catalogued as rs541715049, COSV52828772; called by muse, mutect2, varscan2
- MYT1L | c.2330A>C p.K777T | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.6); catalogued as COSV101219099, COSV67720321; called by muse, mutect2, varscan2
- NAALADL2 | c.196C>A p.L66I | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs963075153, COSV70794806; called by muse, mutect2
- NEB | c.4871A>C p.K1624T | Missense Mutation (SNP) | VAF 30/163 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.339); catalogued as COSV51403025; called by muse, mutect2, varscan2
- OCIAD2 | c.302C>T p.S101L | Missense Mutation (SNP) | VAF 17/176 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56716655; called by muse, mutect2, varscan2
- ODAM | c.323T>G p.V108G | Missense Mutation (SNP) | VAF 71/193 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV68572753; called by muse, mutect2, varscan2
- OPHN1 | c.2274A>C p.E758D | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.001); catalogued as COSV62782402; called by muse, mutect2, varscan2
- OR10A3 | c.268A>C p.T90P | Missense Mutation (SNP) | VAF 45/128 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.265); catalogued as COSV62459488; called by muse, mutect2, varscan2
- OR51B6 | c.155A>T p.N52I | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as COSV66512801; called by muse, mutect2, varscan2
- OR52E2 | c.286T>G p.F96V | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); catalogued as COSV58612584; called by muse, mutect2
- OR5A1 | c.116T>C p.L39P | Missense Mutation (SNP) | VAF 47/140 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as COSV57376708; called by muse, mutect2, varscan2
- OR5T2 | c.179T>G p.L60R | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as COSV57589155; called by muse, mutect2, varscan2
- OSTF1 | c.7A>T p.K3* | Nonsense Mutation (SNP) | VAF 4/24 reads (17%) | catalogued as COSV60547422; called by muse, mutect2
- P4HA3 | c.1510G>A p.G504R | Missense Mutation (SNP) | VAF 24/250 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1393909531, COSV59041872; called by muse, mutect2
- PAFAH1B3 | c.551C>G p.T184S | Missense Mutation (SNP) | VAF 8/111 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.077); catalogued as COSV50570355; called by muse, mutect2
- PAX3 | c.523A>G p.K175E | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.066); catalogued as COSV51339065; called by muse, mutect2, varscan2
- PDE2A | c.1940A>C p.K647T | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV57806736; called by muse, mutect2, varscan2
- PDE3A | c.3226A>T p.T1076S | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.387); catalogued as COSV100762320, COSV62972856; called by muse, mutect2, varscan2
- PIK3CB | c.2788dup p.T930Nfs*8 | Frame Shift Ins (INS) | VAF 16/72 reads (22%) | catalogued as rs1224981079; called by mutect2, varscan2
- PIK3CG | c.727G>A p.A243T | Missense Mutation (SNP) | VAF 62/231 reads (27%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs1207051578, COSV63248587; called by muse, mutect2, varscan2
- PLCG2 | c.819T>G p.I273M | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV63869549; called by muse, mutect2, varscan2
- PLXNA4 | c.3701T>G p.L1234R | Missense Mutation (SNP) | VAF 38/47 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV58125792; called by muse, mutect2, varscan2
- PRR5 | c.706C>T p.R236C (on ENST00000336985 / NM_181333.4; = p.R227C on NM_015366.4) | Missense Mutation (SNP) | VAF 41/150 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.543); catalogued as rs756128125, COSV50060201; called by muse, mutect2, varscan2
- PTPRS | c.3348G>A p.W1116* | Nonsense Mutation (SNP) | VAF 21/116 reads (18%) | catalogued as COSV53619588; called by muse, mutect2, varscan2
- RIMS2 | c.1264A>G p.S422G (on ENST00000666250 / NM_001348490.2; = p.S230G on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.003); catalogued as COSV51681237, COSV51715857; called by muse, mutect2, varscan2
- RP1 | c.184T>C p.S62P | Missense Mutation (SNP) | VAF 29/136 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as COSV55116727; called by muse, mutect2, varscan2
- SEMA4B | c.1738G>A p.A580T | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as rs779317447, COSV60172746; called by muse, mutect2, varscan2
- SERPINB7 | c.490A>G p.S164G | Missense Mutation (SNP) | VAF 39/73 reads (53%) | SIFT tolerated (0.11); PolyPhen benign (0.028); catalogued as COSV60533324, COSV60533883; called by muse, mutect2, varscan2
- SF3A1 | c.2108G>A p.G703D | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.293); catalogued as COSV53168894; called by muse, mutect2, varscan2
- SIGLEC6 | c.400T>C p.S134P | Missense Mutation (SNP) | VAF 22/251 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.212); catalogued as COSV58434227; called by muse, mutect2
- SLC26A7 | c.1678G>A p.E560K | Missense Mutation (SNP) | VAF 41/150 reads (27%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.487); catalogued as COSV52593284; called by muse, mutect2, varscan2
- SLIT2 | c.3230T>G p.F1077C | Missense Mutation (SNP) | VAF 57/284 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.438); catalogued as COSV56572578; called by muse, mutect2, varscan2
- SLX4 | c.3472G>A p.D1158N | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53563990; called by muse, mutect2
- SMC2 | c.2717C>T p.S906F | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT tolerated (0.59); PolyPhen benign (0.024); catalogued as COSV53957717, COSV53958252; called by muse, mutect2, varscan2
- SNRPG | c.10G>T p.A4S | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.035); catalogued as COSV50682631; called by muse, mutect2, varscan2
- SOHLH2 | c.254A>G p.K85R | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs1190348020, COSV58520560, COSV58522859; called by muse, mutect2, varscan2
- SORCS3 | c.2546A>C p.E849A | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV63795085; called by muse, mutect2, varscan2
- SPIRE2 | c.310G>A p.A104T | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.966); catalogued as rs373894738; called by muse, mutect2, varscan2
- SRRM4 | c.1674C>A p.S558R | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.193); catalogued as rs750188540, COSV57416298; called by mutect2, varscan2
- SYNE1 | c.14139A>C p.Q4713H (on ENST00000367255 / NM_182961.4; = p.Q4642H on NM_033071.3) | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as COSV54981164; called by muse, mutect2, varscan2
- TAF1 | c.4304A>C p.N1435T (on ENST00000373790 / NM_138923.4; = p.N1456T on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/85 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52113483; called by muse, mutect2, varscan2
- TBX5 | c.731T>C p.L244P | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as rs1021003518, COSV59861279; called by muse, mutect2, varscan2
- TENM3 | c.6598A>G p.R2200G | Missense Mutation (SNP) | VAF 35/92 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV69308221; called by muse, mutect2, varscan2
- TGIF2LX | c.434A>G p.K145R | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV52213774, COSV52213806; called by muse, mutect2, varscan2
- THBS2 | c.2891T>A p.M964K | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.686); catalogued as COSV64678869; called by muse, mutect2, varscan2
- TMED1 | c.631C>T p.Q211* | Nonsense Mutation (SNP) | VAF 32/75 reads (43%) | catalogued as COSV53034046; called by muse, mutect2, varscan2
- TNFRSF13C | c.257G>A p.G86D | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.751); catalogued as COSV52169607; called by muse, mutect2
- TRO | c.125T>G p.V42G | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.486); catalogued as COSV51501502; called by muse, mutect2
- TRPC4 | c.2533T>C p.F845L (on ENST00000379705 / NM_016179.4; = p.F850L on NM_003306.3) | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0.006); catalogued as COSV100157549, COSV59000027; called by muse, mutect2, varscan2
- TRPC6 | c.671T>G p.I224S | Missense Mutation (SNP) | VAF 19/105 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60254742; called by muse, mutect2, varscan2
- TTN | c.23149A>C p.S7717R (on ENST00000591111; = p.S6790R on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/190 reads (14%) | PolyPhen benign (0.001); catalogued as COSV60061600; called by muse, mutect2, varscan2
- UTP6 | c.1087G>C p.E363Q | Missense Mutation (SNP) | VAF 54/78 reads (69%) | SIFT tolerated (0.08); PolyPhen benign (0.432); catalogued as COSV55573353; called by muse, mutect2, varscan2
- VPS51 | c.940G>A p.G314S | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs902263784, COSV54207298; called by muse, mutect2, varscan2
- XAB2 | c.928A>G p.K310E | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.099); catalogued as COSV64321697; called by muse, mutect2, varscan2
- XIRP2 | c.5512A>T p.R1838* (on ENST00000628543; = p.R2013* on NM_152381.6) | Nonsense Mutation (SNP) | VAF 13/35 reads (37%) | catalogued as COSV54700415; called by muse, mutect2, varscan2
- ZMAT4 | c.371A>G p.K124R | Missense Mutation (SNP) | VAF 70/219 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.05); catalogued as COSV52699274, COSV99908081; called by muse, mutect2, varscan2
- ZNF208 | c.190A>C p.N64H | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.995); catalogued as COSV68105559; called by muse, mutect2, varscan2
- ZNF229 | c.1010G>A p.R337H | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as COSV52160948; called by muse, mutect2, varscan2
- ZNF416 | c.869G>C p.R290T | Missense Mutation (SNP) | VAF 37/192 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.975); catalogued as COSV52184518; called by muse, mutect2, varscan2
- ZNF471 | c.155C>T p.S52L | Missense Mutation (SNP) | VAF 19/215 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs773139042, COSV57291292; called by muse, mutect2
- ZNF804B | c.2912G>T p.G971V | Missense Mutation (SNP) | VAF 26/572 reads (5%) | SIFT tolerated (0.65); PolyPhen benign (0.009); catalogued as COSV60828043; called by muse, mutect2
- ZNF98 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV63336572; called by muse, mutect2, varscan2
- IGKV2-24 | c.215T>C p.L72P | Missense Mutation (SNP) | VAF 65/300 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- KIR2DS4 | c.83A>T p.K28I | Missense Mutation (SNP) | VAF 413/498 reads (83%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.909); called by muse, varscan2
- SMYD5 | c.1204_1207del p.E402Kfs*13 | Frame Shift Del (DEL) | VAF 24/94 reads (26%) | called by mutect2, pindel, varscan2
- SPRED1 | c.1091del p.Y364Ffs*42 | Frame Shift Del (DEL) | VAF 65/149 reads (44%) | called by mutect2, pindel, varscan2
- VILL | c.944_946del p.G315_F316delinsV | In Frame Del (DEL) | VAF 11/29 reads (38%) | called by mutect2, pindel, varscan2
- ZNF677 | c.439_443del p.Q147Cfs*6 | Frame Shift Del (DEL) | VAF 34/76 reads (45%) | called by mutect2, pindel, varscan2
- ABCB4 | c.699T>G p.V233= | Silent (SNP) | VAF 14/337 reads (4%) | catalogued as COSV55935387; called by muse, mutect2
- ADAMTS1 | c.423C>T p.L141= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as COSV53170357; called by muse, mutect2, varscan2
- AKAP17A | c.81C>T p.I27= | Silent (SNP) | VAF 67/155 reads (43%) | catalogued as rs1263763876, COSV58309624; called by muse, mutect2, varscan2
- CFTR | c.2955C>T p.D985= | Silent (SNP) | VAF 19/112 reads (17%) | catalogued as COSV50040476; called by muse, mutect2, varscan2
- CLEC1A | c.471T>C p.S157= | Silent (SNP) | VAF 8/59 reads (14%) | catalogued as COSV59531141; called by mutect2, varscan2
- CLEC1A | c.261T>C p.S87= | Silent (SNP) | VAF 30/78 reads (38%) | catalogued as COSV59532090; called by muse, mutect2, varscan2
- COL12A1 | c.9108A>G p.G3036= | Silent (SNP) | VAF 12/91 reads (13%) | catalogued as rs777425494, COSV59388954; ClinVar: likely benign; called by muse, mutect2, varscan2
- CSMD3 | c.1288A>C p.R430= | Silent (SNP) | VAF 34/129 reads (26%) | catalogued as COSV52181205; called by muse, mutect2, varscan2
- DNAH17 | c.6456G>A p.P2152= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as rs1411826998, COSV101101039; called by muse, mutect2, varscan2
- GABRQ | c.1371A>G p.S457= | Silent (SNP) | VAF 22/194 reads (11%) | catalogued as COSV64781929, COSV64781984; called by muse, mutect2, varscan2
- GRM3 | c.1303T>C p.L435= | Silent (SNP) | VAF 34/550 reads (6%) | catalogued as COSV64471679, COSV64480196; called by muse, mutect2
- H2AC20 | c.45C>T p.A15= | Silent (SNP) | VAF 29/536 reads (5%) | catalogued as rs782582886, COSV58611704, COSV58612589; called by muse, mutect2
- H4C3 | c.54C>T p.R18= | Silent (SNP) | VAF 33/105 reads (31%) | catalogued as rs749328724, COSV58090426, COSV58090550; called by muse, mutect2, varscan2
- IGKV6-21 | c.294A>G p.E98= | Silent (SNP) | VAF 35/194 reads (18%) | catalogued as rs1013680765; called by muse, mutect2, varscan2
- KIAA1549 | c.4956G>C p.V1652= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as COSV54314113, COSV54320819; called by muse, mutect2, varscan2
- KRTAP13-1 | c.477T>G p.S159= | Silent (SNP) | VAF 13/42 reads (31%) | catalogued as COSV100819828; called by muse, mutect2, varscan2
- MOB1B | c.558T>C p.F186= | Silent (SNP) | VAF 30/83 reads (36%) | catalogued as rs1370950439, COSV58673892; called by muse, mutect2, varscan2
- MYT1 | c.1761C>T p.Y587= | Silent (SNP) | VAF 30/76 reads (39%) | catalogued as rs779615817, COSV60505779; called by muse, mutect2, varscan2
- NSUN7 | c.12C>G p.S4= | Silent (SNP) | VAF 21/85 reads (25%) | catalogued as COSV57273842; called by muse, mutect2, varscan2
- OR10G7 | c.735C>T p.I245= | Silent (SNP) | VAF 49/93 reads (53%) | catalogued as rs151111393; called by muse, mutect2, varscan2
- OR52A5 | c.258C>T p.I86= | Silent (SNP) | VAF 14/54 reads (26%) | catalogued as COSV56615249, COSV56615421; called by muse, mutect2, varscan2
- OR5AC2 | c.507T>G p.T169= | Silent (SNP) | VAF 18/124 reads (15%) | catalogued as COSV62279496; called by muse, mutect2, varscan2
- PABPC1L | c.906C>T p.D302= | Silent (SNP) | VAF 110/192 reads (57%) | catalogued as rs1380845731, COSV53840523; called by muse, mutect2, varscan2
- PCLO | c.1170T>C p.A390= | Silent (SNP) | VAF 15/69 reads (22%) | catalogued as COSV61635247; called by muse, mutect2, varscan2
- PMEL | c.535C>T p.L179= | Silent (SNP) | VAF 27/109 reads (25%) | catalogued as COSV59386041; called by muse, mutect2, varscan2
- PRND | c.333C>T p.A111= | Silent (SNP) | VAF 11/81 reads (14%) | catalogued as COSV59896529; called by muse, mutect2, varscan2
- SDK2 | c.5178T>C p.A1726= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as COSV66186016; called by muse, mutect2, varscan2
- SPATA31E1 | c.3831G>A p.R1277= | Silent (SNP) | VAF 16/137 reads (12%) | catalogued as COSV57789834; called by muse, mutect2, varscan2
- SRGAP2 | c.1455C>T p.C485= (on ENST00000624873 / NM_001170637.4; = p.C486= on NM_015326.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 23/45 reads (51%) | catalogued as rs1553363452, COSV55337456; called by muse, mutect2, varscan2
- SUSD2 | c.1473G>A p.T491= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as rs930131299, COSV64203897; called by muse, mutect2, varscan2
- TMEM248 | c.564C>A p.L188= | Silent (SNP) | VAF 22/62 reads (35%) | catalogued as COSV58577426; called by muse, mutect2, varscan2
- TNXB | c.4461G>A p.T1487= (on ENST00000647633; = p.T1240= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs375134509; called by muse, mutect2, varscan2
- TSR1 | c.1353G>A p.G451= | Silent (SNP) | VAF 13/74 reads (18%) | catalogued as COSV56785000; called by muse, mutect2, varscan2
- TSTD2 | c.1104C>G p.L368= | Silent (SNP) | VAF 19/64 reads (30%) | catalogued as COSV52247691; called by muse, mutect2, varscan2
- VAT1L | c.852G>A p.E284= | Silent (SNP) | VAF 26/85 reads (31%) | catalogued as COSV56820113; called by muse, mutect2, varscan2
- VIP | c.198T>C p.A66= | Silent (SNP) | VAF 7/56 reads (13%) | catalogued as COSV65888984; called by muse, mutect2, varscan2
- ZFPM2 | c.1335T>C p.T445= | Silent (SNP) | VAF 19/75 reads (25%) | catalogued as COSV65872513, COSV65873685; called by muse, mutect2, varscan2
- ZNF446 | c.510C>T p.P170= | Silent (SNP) | VAF 7/73 reads (10%) | catalogued as COSV52180747; called by muse, mutect2
- ZNF785 | c.1098C>T p.S366= | Silent (SNP) | VAF 32/184 reads (17%) | catalogued as rs754271979, COSV67876311; called by muse, mutect2, varscan2
- ADAM19 | chr5:157480954 T>G | 3'Flank (SNP) | VAF 12/62 reads (19%) | catalogued as COSV57430111; called by muse, mutect2, varscan2
- MIR519B | n.35T>G | RNA (SNP) | VAF 36/167 reads (22%) | called by muse, mutect2, varscan2
- SNORD116-29 | n.23del | RNA (DEL) | VAF 31/70 reads (44%) | called by mutect2, pindel, varscan2
